Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2PL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2PL-01A (Primary Tumor).

HMMA Discrepancy		☒
Qualifying Primary Malignancy		☒

PAGE: 1

RUN DATE:
RUN TIME:
BY:

PATIENT: **233.1**
AGE/SEX: **DOB:**
ACCT #:
CLIENT PATIENT ID:

SUBM DR:
LOC:

SPEC #: PN: Status: Obtained: Received:

CLINICAL HISTORY:
233.1

SPECIMEN/PROCEDURE:
1. CERVIX - BX

ICD-0-3
carcinoma, squamous cell
large cell, non-keratinizing 8072/3
Site: cervix, NOS C53.9
lw 8/23/11

IMPRESSION:

CERVICAL BIOPSY AT

Squamous cell carcinoma, large cell, non-keratinizing, with stromal invasion.

Dictated
Entered:

GROSS DESCRIPTION:

This case is part of the

Received in formalin, labeled "7:00" and with the patient's name, is one pink-tan rubbery portion of tissue, 1.0 x 0.5 x 0.2 cm. The specimen is bisected and entirely submitted in one cassette.

Dictated
Entered:

CPT Codes:
CERVICAL BIOPSY

ICD9 Codes:

Electronically Signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file d9db225c-e840-4761-b99c-3352de70601e (TCGA-EK-A2PL.B51554EF-AA39-4A99-BC15-A80EC759316E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).